FM case AD1026 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/6d9d6cb9-652f-4749-b4c5-aa9e6b80de69

Female, 69.7 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the uterus; primary biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
